Surgical pathology report (de-identified scan), TCGA case TCGA-E8-A419, project TCGA-THCA (Thyroid Carcinoma), tissue source site Asterand, specimen TCGA-E8-A419-01A (Primary Tumor).

Procurement Date:

Laterality:

Path Report:Tumor size (in cm):2.5 x 3 x 2 cm

Histologic type: Papillary thyroid carcinoma

Tumor extent: not specified

Tumor laterality: Left

Tumor focality: Unifocal

ICD-O3

Carcinoma, papillary, thyroid

8260/3

Site: thyroid, Nos

C73.9

7-20-12 RD

Reviewed initials	[Signature]	

7/9/12

Source: NCI Genomic Data Commons file 4d5ed014-a866-4802-98bc-2eecabe3f97d (TCGA-E8-A419.96AD2BE9-B8DF-4696-BD0F-61FA2CA60871.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).